BEATAML1.0 case 2814 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/a45e2367-38d9-4771-9c55-d19d0ee55978

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Acute myeloid leukemia with mutated NPM1: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.7 years (17,420 days); Progression or recurrence: no.

Biospecimens (2 samples)
- Sample BA3270D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA3270R: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
